CCDI case PBBTCE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/f6827c7b-6a87-4ad9-b7b1-1295cb810e7c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 7.7 years (2,812 days).

Biospecimens (3 samples)
- Sample 0DGIK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGIK2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VH: Tissue type: Tumor; Specimen type: Solid Tissue.
